Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A71E, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A71E-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell NOS
807013
Site: Floor of mouth NOS
C04.9
JW 8/9/13

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Floor of mouth

- 1 - "Lymph Nodes – Level 1, 2 and 3 – Right":
- Absence of neoplasia: (0/22)
- Submandibular gland uninvolved by carcinoma.
- 2 - "Lymph Nodes – Level 1, 2 and 3 – Left":
- Absence of neoplasia: (0/26)
- Submandibular gland uninvolved by carcinoma.
- 3 - "Shared of right miloioide muscle"
- Absence of neoplasia
- 4 - "Pelvi- mandibulectomy central arch":
- Squamous cell carcinoma basaloid type
- Tumor size: 4,5x3,6x2,3 cm
- Tumor involves floor of mouth, gingiva, tongue and jaw
- Intense stromal desmoplasia
- Perineural invasion: not identified
- Lymph-vascular invasion: present
- Foci of carcinoma in situ
- Margins uninvolved by invasive tumor
- 5- "Ment of subcutaneous":
- Absence of neoplasia

Source: NCI Genomic Data Commons file f1e93717-39fa-47ba-a7e0-a261d88bb266 (TCGA-UF-A71E.881A6334-4EEE-4468-AD5A-5F3E83C911EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).